CGCI case BLGSP-71-06-00283 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c9e0f3c5-f996-435d-8d2a-d32420aaaf9b

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 6 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bones of skull and face and associated joints; Classification of tumor: primary; Age at diagnosis: 6.2 years (2,260 days); Year of diagnosis: 2016; Method of diagnosis: Incisional Biopsy; Ann Arbor pathologic stage: Stage III; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 227 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Endemic; Max tumor bulk site: Maxilla; Sites of involvement: Bone, NOS / Eye / Maxilla.
   Pathology details: Lymph node involved site: Inguinal.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Cervical, NOS; Tumor largest dimension diameter: 12 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: COP; Days to treatment start: 1 day; Days to treatment end: 1 day; Number of cycles: 1; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 1 day; Days to treatment end: 1 day; Number of cycles: 1; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Adjuvant; Regimen or line of therapy: COM; Days to treatment start: 8 days; Days to treatment end: 113 days; Number of cycles: 6; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Methotrexate + Vincristine; Treatment intent type: Adjuvant; Days to treatment start: 8 days; Days to treatment end: 113 days; Number of cycles: 6; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Recurrent Disease; Regimen or line of therapy: DHAP; Days to treatment start: 227 days; Number of cycles: 4.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Cytarabine + Dexamethasone; Initial disease status: Recurrent Disease; Days to treatment start: 227 days; Number of cycles: 4.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Radiation Therapy, NOS, for recurrent disease; adjuvant Radiation Therapy, NOS; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Days to follow up: 0 days; Karnofsky performance status: 40; ECOG performance status: 3.
- Days to follow up: 8 days; Disease response: With Tumor.
- Days to follow up: 131 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Bones of skull and face and associated joints; Days to recurrence: 131 days.
- Days to follow up: 227 days; Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- Lactate Dehydrogenase 463 [Blood test normal range upper: 340].

Other clinical attributes
- Day 0: Weight: 26 kg; Height: 110 cm; BMI: 21.5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-06-00283-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Maxilla; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Incisional Biopsy; Tissue collection type: Prospective.
  Slide BLGSP-71-06-00283-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 5.
  Slide BLGSP-71-06-00283-01A-01-S1-HE: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-06-00283-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-06-00283-01-HE-1: Tissue microarray coordinates: C2,D2,A4.
  Slide BLGSP-71-06-00283-01-BCL6: Tissue microarray coordinates: C2,D2,A4.
  Slide BLGSP-71-06-00283-01-Ki67: Tissue microarray coordinates: C2,D2,A4.
  Slide BLGSP-71-06-00283-01-CD20: Tissue microarray coordinates: C2,D2,A4.
  Slide BLGSP-71-06-00283-01-BCL2: Tissue microarray coordinates: C2,D2,A4.
  Slide BLGSP-71-06-00283-01-CD3: Tissue microarray coordinates: C2,D2,A4.
  Slide BLGSP-71-06-00283-01-CD10: Tissue microarray coordinates: C2,D2,A4.
- Sample BLGSP-71-06-00283-99A: Sample type: Granulocytes; Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen; Days to sample procurement: 8 days; Method of sample procurement: Blood Draw; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Days from index date to last known alive: 8; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 3; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Bone; Extranodal involvement site: Eye.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 463; Immunophenotypic analysis method: Immunohistochemistry.
- Follow-up form: Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event type: Locoregional Recurrence; New tumor event site other: Right maxilla; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Treatments, Treatment 1: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 1.
- Treatments, Treatment 2: Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 6.
- Treatments, Treatment 3: Therapy regimen: Recurrence; Chemo end reporting period: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 4.
